TCGA case TCGA-A4-7996 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d1a96a7a-2b11-48ce-869e-1fa19c1eb0a5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.8 years (22,559 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 506 days (1.4 years).
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 1.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 63.1 years (23,052 days); Days to diagnosis: 493 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 493 days (1.3 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Days to follow up: 49 days; Disease response: Tumor Free.
- Day 493 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 493 days (1.3 years).
- Days to follow up: 506 days (1.4 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A4-7996-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-A4-7996-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-A4-7996-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A4-7996-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: No; Tobacco smoking history indicator: 1.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 506 days; disease-specific survival: no event (censored), 506 days; disease-free interval: event (new tumor event after initially disease-free), 493 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 493 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A4-7996-01A-11D-2200-01): tumor purity 0.67, ploidy 2.14, whole-genome doublings 0.
